Somatic mutation profile of tumor specimen ALCH-B2AQ-TTP1-B (aliquot ALCH-B2AQ-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B2AQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.7 years (20,697 days).
Specimen ALCH-B2AQ-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e1a307d-f0ea-4ab6-8262-993a902599f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AQ-NB1-A (Blood Derived Normal), aliquot ALCH-B2AQ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5b579fa-71eb-4120-bf63-f2c91379eee3

The open-access MAF lists 708 somatic variants for this specimen: 495 protein-altering or splice-affecting, 153 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 411, Silent 153, Nonsense Mutation 37, Intron 30, Splice Site 17, Frame Shift Del 10, 3'UTR 10, Frame Shift Ins 10, Splice Region 8, RNA 8, 5'Flank 6, 5'UTR 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN8A | c.2003C>T p.T668I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs758253791, CM161534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 100/600 reads (17%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.12784C>T p.H4262Y | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs1030461699; called by muse, mutect2, varscan2
- ACSM1 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 34/409 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs751725508; called by muse, mutect2
- ACSM5 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 50/473 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs141553052; called by muse, mutect2
- ADAMTS9 | c.2717G>T p.R906M | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99899215; called by muse, mutect2, varscan2
- AGL | c.1877A>T p.H626L | Missense Mutation (SNP) | VAF 66/748 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM128735; called by muse, mutect2
- AHNAK | c.12224G>T p.G4075V | Missense Mutation (SNP) | VAF 70/528 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.06); catalogued as COSV57224849; called by muse, mutect2, varscan2
- AHNAK2 | c.11575G>A p.D3859N | Missense Mutation (SNP) | VAF 55/584 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); catalogued as rs1356084881; called by muse, mutect2
- ANKRD30A | c.3148G>T p.E1050* (on ENST00000611781; = p.E994* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 24/257 reads (9%) | catalogued as COSV64605238; called by muse, mutect2, varscan2
- ATL3 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV60297136; called by muse, mutect2, varscan2
- ATP2A3 | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988738; called by muse, mutect2, varscan2
- B3GAT1 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.029); catalogued as COSV56995067, COSV99074089; called by muse, mutect2, varscan2
- BBS7 | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 82/480 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52656256; called by muse, mutect2, varscan2
- BMPR1B | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs754365645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV99775225; called by muse, mutect2
- BRINP1 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 113/685 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777077; called by muse, mutect2, varscan2
- C7orf57 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV100817302; called by muse, mutect2, varscan2
- CACNA1E | c.1150del p.R384Vfs*4 | Frame Shift Del (DEL) | VAF 88/564 reads (16%) | catalogued as COSV62420197; called by pindel, varscan2
- CBL | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50645966; called by muse, mutect2, varscan2
- CCDC146 | c.1920-1G>A p.X640_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as rs1001616116; called by muse, mutect2, varscan2
- CCDC33 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 32/453 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs373900085; called by muse, mutect2
- CDH8 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV54876173; called by muse, mutect2
- CEP350 | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV62486030; called by muse, mutect2
- CFAP47 | c.4820C>G p.P1607R | Missense Mutation (SNP) | VAF 49/596 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1191221219; called by muse, mutect2
- CFAP58 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV100459145; called by mutect2, varscan2
- CHST2 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58886767; called by muse, mutect2, varscan2
- CIC | c.3641G>T p.R1214L | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as COSV99358994; called by muse, mutect2, varscan2
- CNTNAP5 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70485983; called by muse, mutect2
- COG8 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 98/1042 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs758158339; called by muse, mutect2
- COL22A1 | c.4274C>G p.T1425R | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs1339747295, COSV57368217; called by muse, mutect2, varscan2
- CPT1C | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54919325; called by muse, mutect2, varscan2
- CPXM1 | c.966C>G p.I322M | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV101013719; called by muse, mutect2
- CPXM2 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1210313339; called by muse, mutect2
- CREB5 | c.465-1G>T p.X155_splice (on ENST00000357727 / NM_182898.4; = p.X148_splice on NM_004904.3) | Splice Site (SNP) | VAF 44/272 reads (16%) | catalogued as COSV100745680; called by muse, mutect2, varscan2
- CREBBP | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 54/1064 reads (5%) | catalogued as COSV52119623, COSV52122303; called by muse, mutect2
- CSDE1 | c.1930G>T p.D644Y (on ENST00000358528 / NM_001007553.3; = p.D613Y on NM_007158.6) | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138627779; called by muse, mutect2, varscan2
- CSMD3 | c.8845G>T p.E2949* (on ENST00000297405 / NM_001363185.1; = p.E2780* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 23/281 reads (8%) | catalogued as COSV52131625, COSV52243238; called by muse, mutect2
- DEFB121 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 89/649 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.076); catalogued as rs967966294; called by muse, mutect2, varscan2
- DGKB | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51814491; called by muse, mutect2, varscan2
- DGKI | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 30/166 reads (18%) | catalogued as COSV55967600; called by muse, mutect2, varscan2
- DMD | c.11003C>T p.P3668L | Missense Mutation (SNP) | VAF 86/662 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58905976; called by muse, varscan2
- DMD | c.10963G>T p.G3655W | Missense Mutation (SNP) | VAF 79/609 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100626288; called by muse, varscan2
- DMD | c.5043G>T p.M1681I | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1045187121; called by muse, mutect2
- DNTT | c.507+1G>T p.X169_splice | Splice Site (SNP) | VAF 37/224 reads (17%) | catalogued as COSV64523237; called by muse, mutect2, varscan2
- EFHB | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1352640509, COSV99859086; called by muse, mutect2
- EP300 | c.2431G>C p.G811R | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99609088; called by muse, mutect2
- EPHB2 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 32/572 reads (6%) | catalogued as COSV101006739; called by muse, mutect2
- EYS | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV65546188; called by muse, mutect2, varscan2
- FAM3A | c.152-8C>A | Splice Region (SNP) | VAF 36/362 reads (10%) | catalogued as rs1451592664; called by muse, mutect2, varscan2
- FAM71B | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 78/519 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57228351; called by muse, mutect2, varscan2
- FBXO16 | c.99G>T p.R33= | Splice Region (SNP) | VAF 29/312 reads (9%) | catalogued as rs373752408; called by muse, mutect2
- FEZF2 | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 54/529 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51862538; called by muse, mutect2
- FNDC4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 16/487 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV99254025; called by muse, mutect2
- FSTL5 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV60228052; called by muse, mutect2, varscan2
- GABRB3 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs1453012489, COSV54657264, COSV54676874; called by muse, mutect2
- GABRG1 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950303; called by muse, mutect2
- GAD2 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99393952; called by muse, mutect2
- GPC5 | c.930C>G p.Y310* | Nonsense Mutation (SNP) | VAF 18/242 reads (7%) | catalogued as COSV65586625; called by muse, mutect2
- GTF2IRD1 | c.2153G>A p.G718E (on ENST00000265755 / NM_016328.3; = p.G703E on NM_005685.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56088596; called by muse, mutect2
- HAS1 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 158/547 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768928691; called by muse, mutect2, varscan2
- HCFC1 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV104415485; called by muse, mutect2, varscan2
- HDAC3 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59495491; called by muse, mutect2
- HMX3 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV63501906; called by muse, mutect2, varscan2
- HOXA3 | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100415539, COSV57828754; called by muse, mutect2
- HSPH1 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 85/410 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs1018221389; called by muse, mutect2, varscan2
- HUWE1 | c.10822C>A p.L3608I | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs782349344; called by muse, mutect2
- IL21R | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100559922; called by muse, mutect2, varscan2
- INHBA | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); catalogued as COSV54223981; called by muse, mutect2
- IVL | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 52/534 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV100908306, COSV64215387; called by muse, mutect2
- JAK2 | c.2980G>T p.D994Y | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104431544; called by muse, mutect2
- JAKMIP2 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54602896; called by muse, mutect2, varscan2
- KCNMB4 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.542); catalogued as COSV50691492; called by muse, mutect2, varscan2
- KIRREL1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100779706; called by muse, varscan2
- LRFN4 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs1355003703; called by muse, mutect2, varscan2
- LRRC9 | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205974967; called by muse, mutect2
- MAGED2 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54496986; called by muse, mutect2
- MICAL3 | c.226A>T p.K76* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52901087; called by muse, mutect2, varscan2
- MMUT | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM060366; called by muse, mutect2, varscan2
- MN1 | c.3892G>T p.V1298L | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100180192; called by muse, mutect2, varscan2
- MUC16 | c.7669A>G p.T2557A | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV104432125; called by muse, mutect2, varscan2
- MUC4 | c.2030C>A p.S677* | Nonsense Mutation (SNP) | VAF 24/602 reads (4%) | catalogued as rs750548622, COSV62133934; called by muse, mutect2
- MYH2 | c.1542C>G p.I514M | Missense Mutation (SNP) | VAF 26/744 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV55440907; called by muse, mutect2
- NDN | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV59360050; called by muse, mutect2, varscan2
- NEXMIF | c.3719G>T p.G1240V | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV99029806; called by muse, mutect2, varscan2
- NF1 | c.4292del p.P1431Hfs*9 (on ENST00000358273 / NM_001042492.3; = p.P1410Hfs*9 on NM_000267.3) | Frame Shift Del (DEL) | VAF 41/403 reads (10%) | catalogued as COSV62208716; called by mutect2, pindel, varscan2
- NHLRC4 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs752615912; called by muse, mutect2, varscan2
- NHS | c.2131G>C p.A711P | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV66275062; called by muse, mutect2, varscan2
- NME9 | c.562G>A p.E188K (on ENST00000333911 / NM_001349024.2; = p.E127K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV58622655; called by muse, mutect2
- NPHP4 | c.2759G>T p.R920M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV65394704; called by muse, mutect2, varscan2
- NUTM1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV60995244; called by muse, mutect2
- NXPH2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs1289010307; called by muse, varscan2
- OR4A16 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as rs374770148; called by muse, mutect2, varscan2
- OR4C16 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV58942583; called by muse, mutect2, varscan2
- OR51L1 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205141361; called by muse, mutect2
- OR5L1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs138368201; called by muse, mutect2, varscan2
- PCDHB1 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60630243; called by muse, mutect2, varscan2
- PCDHB6 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs572160511; called by muse, mutect2, varscan2
- PCDHB8 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 154/2972 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50848832; called by muse, mutect2
- PCSK7 | c.1378C>G p.H460D | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1190655295, COSV58006849; called by muse, mutect2
- PHF6 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 83/752 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs1273843884; called by muse, mutect2, varscan2
- PKHD1 | c.8249G>A p.G2750E | Missense Mutation (SNP) | VAF 33/820 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348552972; called by muse, mutect2
- PLCXD1 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV58204900; called by muse, mutect2, varscan2
- PLXNC1 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); catalogued as COSV99314124; called by muse, mutect2, varscan2
- PRLR | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 55/657 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51495662; called by muse, mutect2
- PRND | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 214/703 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs778112087, COSV59896961; called by muse, mutect2, varscan2
- PTPRR | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51739696; called by muse, mutect2, varscan2
- PTPRT | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62019827; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 60/241 reads (25%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAG1 | c.1682G>T p.R561L | Missense Mutation (SNP) | VAF 95/543 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as CM981694, COSV55024882; called by muse, mutect2, varscan2
- REG1A | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 136/695 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777579151, COSV52071733, COSV52072168; called by muse, mutect2, varscan2
- RGS7 | c.722G>A p.S241N | Missense Mutation (SNP) | VAF 81/618 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV100471897; called by muse, mutect2, varscan2
- RHOT1 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1266417602; called by muse, mutect2, varscan2
- RNF113A | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65097750; called by muse, mutect2, varscan2
- RPAP1 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1205228272, COSV58540008; called by muse, mutect2
- RRP7A | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1425057669; called by muse, mutect2, varscan2
- RTL8C | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 41/496 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV99924261; called by muse, mutect2
- SCAF1 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1289410641, COSV62183197; called by muse, mutect2, varscan2
- SHANK2 | c.3664G>C p.A1222P | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600959, COSV99573203; called by muse, mutect2, varscan2
- SHISAL1 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs1453672483; called by muse, mutect2
- SI | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV52300766; called by muse, mutect2, varscan2
- SIPA1L2 | c.4805C>A p.T1602K | Missense Mutation (SNP) | VAF 61/562 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.068); catalogued as rs774023610; called by muse, mutect2, varscan2
- SLC22A25 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs139002638, COSV60598593; called by muse, mutect2, varscan2
- SLC39A12 | c.1105T>A p.Y369N | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66200991; called by muse, mutect2, varscan2
- SMG5 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 58/507 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1024380151; called by muse, varscan2
- SORCS1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53876887; called by muse, mutect2, varscan2
- SRCAP | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52675871; called by muse, mutect2, varscan2
- TIFAB | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 222/793 reads (28%) | catalogued as COSV72345920; called by muse, mutect2, varscan2
- TMEM265 | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as COSV52672399; called by muse, mutect2
- TMEM72 | c.336C>A p.H112Q | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101273505; called by muse, mutect2, varscan2
- TREX2 | c.311C>G p.T104R (on ENST00000334497; = p.T61R on NM_080701.3) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57851036; called by muse, mutect2, varscan2
- TRIM15 | c.236del p.G79Efs*59 | Frame Shift Del (DEL) | VAF 74/561 reads (13%) | catalogued as COSV64990339; called by mutect2, pindel, varscan2
- TUBA3C | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV67138785; called by muse, mutect2
- USH2A | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475577009; called by muse, mutect2
- XIRP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99736892; called by muse, mutect2, varscan2
- XRN2 | c.1773+1G>T p.X591_splice | Splice Site (SNP) | VAF 83/384 reads (22%) | catalogued as rs1324545184; called by muse, mutect2, varscan2
- YKT6 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 22/485 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV99790608; called by muse, mutect2
- ZIC3 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54976500; called by muse, mutect2, varscan2
- ZNF189 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs775403415; called by muse, mutect2, varscan2
- ZNF318 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58930547; called by muse, mutect2
- ZNF382 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs773090722, COSV99035401; called by muse, mutect2, varscan2
- ZNF519 | c.1619G>T p.R540M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1471480298; called by mutect2, varscan2
- ZNF827 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 68/469 reads (14%) | catalogued as COSV65226644; called by muse, mutect2, varscan2
- AC242842.3 | c.5320G>T p.G1774* | Nonsense Mutation (SNP) | VAF 24/1265 reads (2%) | called by muse, mutect2
- ACSF3 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 47/455 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ACTRT1 | c.818C>A p.P273Q | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2
- ADAMTS6 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA1 | c.1322T>A p.L441H | Missense Mutation (SNP) | VAF 17/387 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ADGRG5 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AHNAK2 | c.8527G>C p.V2843L | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- AHNAK2 | c.7852G>T p.V2618F | Missense Mutation (SNP) | VAF 56/650 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2
- AIM2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2
- AIM2 | c.817-1G>A p.X273_splice | Splice Site (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- AIPL1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 98/508 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AKAP17A | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 104/961 reads (11%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); called by muse, mutect2
- AMER1 | c.2195T>C p.M732T | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- AMY2A | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.9979G>A p.E3327K | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.23); called by muse, mutect2
- ANKRD17 | c.5790G>T p.R1930S | Missense Mutation (SNP) | VAF 145/811 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ANTXRL | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 47/661 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- AOX1 | c.3844G>C p.A1282P | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APBB1IP | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2
- APMAP | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- APOBR | c.2612A>T p.K871M (on ENST00000431282; = p.K880M on NM_018690.4) | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- APOOL | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 49/776 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ASMT | c.641T>A p.V214E (on ENST00000381229; = p.V242E on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/905 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATG4C | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ATP1A2 | c.2072C>A p.S691Y | Missense Mutation (SNP) | VAF 186/910 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2B2 | c.1496C>T p.T499I (on ENST00000352432; = p.T465I on NM_001683.5) | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AZGP1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- BBOX1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 47/477 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEGAIN | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BEX4 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BMPER | c.199dup p.C67Lfs*14 | Frame Shift Ins (INS) | VAF 64/664 reads (10%) | called by mutect2, pindel
- BRINP1 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- BRINP2 | c.1799G>T p.S600I | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C16orf96 | c.3250C>A p.P1084T | Missense Mutation (SNP) | VAF 87/497 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C1QB | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CACNA1I | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNG2 | c.874A>T p.R292W | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CADPS2 | c.3562A>G p.I1188V | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CAMSAP1 | c.3043G>T p.V1015F | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CASK | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 49/481 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CASQ2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 50/740 reads (7%) | called by muse, mutect2
- CBLL2 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBWD3 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 63/1029 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCDC168 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC191 | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- CCNC | c.749T>G p.M250R | Missense Mutation (SNP) | VAF 81/407 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CD109 | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CD1B | c.21A>T p.Q7H | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CD1E | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD207 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 78/305 reads (26%) | called by muse, mutect2, varscan2
- CD247 | c.162+1G>T p.X54_splice | Splice Site (SNP) | VAF 108/879 reads (12%) | called by muse, mutect2, varscan2
- CD300E | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 120/389 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CD4 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC42BPG | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 39/334 reads (12%) | called by muse, mutect2, varscan2
- CDH2 | c.2716G>C p.D906H | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELA2B | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 90/460 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CEP97 | c.1817+5G>T | Splice Region (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- CFAP46 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 39/532 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFTR | c.4198T>A p.C1400S | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST8 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 151/537 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CIZ1 | c.1862T>A p.L621Q | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CNGA2 | c.1712A>T p.E571V | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL28A1 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CR2 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 113/731 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CRYM | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 77/491 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CST4 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CTPS2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTR9 | c.3336C>G p.S1112R | Missense Mutation (SNP) | VAF 17/606 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2
- CYP11B1 | c.1308G>T p.R436S | Missense Mutation (SNP) | VAF 47/784 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- CYP26B1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 50/730 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- CYP4V2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DAPK1 | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, varscan2
- DCAF8L1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DENND1A | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DGKK | c.2724C>A p.Y908* | Nonsense Mutation (SNP) | VAF 48/405 reads (12%) | called by muse, mutect2, varscan2
- DIAPH2 | c.3305G>T p.*1102Lext*12 | Nonstop Mutation (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- DIDO1 | c.6038G>A p.G2013D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.333); called by mutect2, varscan2
- DISP3 | c.3040G>T p.V1014F | Missense Mutation (SNP) | VAF 25/429 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAAF6 | c.188C>G p.P63R | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.3746A>T p.Q1249L | Missense Mutation (SNP) | VAF 42/463 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- DSE | c.1223C>A p.A408E | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DYNC1H1 | c.5523G>T p.Q1841H | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DYNC2H1 | c.9820-2A>T p.X3274_splice | Splice Site (SNP) | VAF 81/265 reads (31%) | called by muse, mutect2, varscan2
- EDA2R | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EIF3B | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1869A>C p.Q623H | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EP300 | c.2104A>T p.M702L | Missense Mutation (SNP) | VAF 179/1103 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ERAP2 | c.2027C>A p.T676N | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ERBB4 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EYS | c.2293G>A p.G765R | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- FAM118A | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM166C | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM199X | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAM83C | c.2063A>G p.Q688R | Missense Mutation (SNP) | VAF 55/344 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM83C | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FARP1 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L5 | c.3855G>C p.K1285N (on ENST00000623019; = p.K1258N on NM_001293083.2) | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FFAR3 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 160/807 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLNA | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- FLT4 | c.3807+4C>A | Splice Region (SNP) | VAF 50/350 reads (14%) | called by muse, mutect2, varscan2
- FN1 | c.810T>A p.C270* | Nonsense Mutation (SNP) | VAF 156/659 reads (24%) | called by muse, mutect2, varscan2
- FOXJ2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 72/670 reads (11%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- FOXL1 | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2
- FRMPD4 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FRYL | c.7243G>C p.D2415H | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRA3 | c.1192A>C p.I398L | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRB3 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 24/434 reads (6%) | PolyPhen benign (0.081); called by muse, mutect2
- GALNT8 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GFRA2 | c.969C>A p.C323* | Nonsense Mutation (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- GJB4 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 21/458 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GK | c.730-1G>C p.X244_splice | Splice Site (SNP) | VAF 26/824 reads (3%) | called by muse, mutect2
- GMCL1 | c.1365-2A>T p.X455_splice | Splice Site (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- GNB3 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GPATCH2 | c.1503G>T p.Q501H | Missense Mutation (SNP) | VAF 96/691 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPC6 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GPR139 | c.993C>A p.N331K | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- GPR26 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 28/694 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- GPRIN1 | c.1464C>A p.N488K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GREM2 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GRIK2 | c.2449G>T p.V817F | Missense Mutation (SNP) | VAF 100/583 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HAPLN3 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- HCRTR2 | c.632A>G p.D211G | Missense Mutation (SNP) | VAF 83/753 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HDLBP | c.2313G>T p.Q771H | Missense Mutation (SNP) | VAF 124/584 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- HELZ | c.4961C>A p.P1654Q | Missense Mutation (SNP) | VAF 146/608 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- HK3 | c.322del p.V108* | Frame Shift Del (DEL) | VAF 93/684 reads (14%) | called by pindel, varscan2
- HSF1 | c.564+5G>T | Splice Region (SNP) | VAF 29/342 reads (8%) | called by muse, mutect2
- HTATSF1 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- HYDIN | c.6596G>T p.G2199V | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2
- IDS | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | called by mutect2, varscan2
- IFNL1 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 186/519 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IFRD2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2
- IGHM | c.1231T>A p.Y411N | Missense Mutation (SNP) | VAF 52/622 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- IGHV3-21 | c.46+2T>C p.X16_splice | Splice Site (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- IL4I1 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 21/590 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.257); called by muse, mutect2
- IMPDH2 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- INSYN2B | c.1243C>G p.R415G | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ITSN2 | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- JAKMIP1 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- JAKMIP2 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT8 | c.1006A>G p.S336G | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNA6 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCND3 | c.1603T>A p.S535T | Missense Mutation (SNP) | VAF 95/1204 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.223); called by muse, mutect2
- KCNK13 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- KCNT2 | c.1814G>C p.S605T | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0319L | c.574_587del p.P192Yfs*9 | Frame Shift Del (DEL) | VAF 61/386 reads (16%) | called by mutect2, pindel, varscan2
- KIAA1143 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 32/760 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- KIAA1210 | c.3092dup p.R1032Pfs*10 | Frame Shift Ins (INS) | VAF 30/285 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KIAA1671 | c.4471G>T p.A1491S | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- KIF17 | c.2565G>C p.M855I | Missense Mutation (SNP) | VAF 33/487 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2
- KIF4A | c.1453G>C p.A485P | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2
- KIR3DX1 | n.357-1G>A | Splice Site (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- KLHL42 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 104/691 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- KLHL42 | c.1392G>T p.L464F | Missense Mutation (SNP) | VAF 102/684 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KREMEN2 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- L3MBTL2 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- LAMA3 | c.5698C>T p.Q1900* (on ENST00000313654 / NM_198129.4; = p.Q291* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 34/694 reads (5%) | called by muse, mutect2
- LANCL2 | c.1259-1G>T p.X420_splice | Splice Site (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- LDAH | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 85/564 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LIX1L | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.7388-1G>T p.X2463_splice | Splice Site (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2, varscan2
- LRRC14B | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LSAMP | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 69/512 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAGEA1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MAGEB6B | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 70/529 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MFAP3 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MFF | c.761dup p.L254Ffs*11 | Frame Shift Ins (INS) | VAF 115/563 reads (20%) | called by mutect2, pindel, varscan2
- MKS1 | c.1230C>A p.Y410* | Nonsense Mutation (SNP) | VAF 34/1163 reads (3%) | called by muse, mutect2
- MLYCD | c.1141A>T p.S381C | Missense Mutation (SNP) | VAF 51/442 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MMRN1 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MOK | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 77/439 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MORC1 | c.2187G>T p.L729= | Splice Region (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- MOSPD3 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRGPRX3 | c.172A>G p.R58G | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MUC16 | c.41878-1G>T p.X13960_splice | Splice Site (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2
- MYH4 | c.5271G>C p.E1757D | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2
- MYO18B | c.4262C>T p.S1421L | Missense Mutation (SNP) | VAF 26/525 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.865); called by muse, mutect2
- MYOM2 | c.2734G>T p.G912C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2
- MYOM2 | c.3659A>C p.Y1220S | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYT1 | c.166dup p.L56Pfs*11 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel
- MYT1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 128/520 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- NAB2 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 132/321 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.1129G>T p.A377S (on ENST00000396087 / NM_001244963.2; = p.A354S on NM_145117.5) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCBP3 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NDNF | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NEURL1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEUROD4 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- NF1 | c.60+8G>T | Splice Region (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- NFASC | c.1950dup p.G651Rfs*4 (on ENST00000339876 / NM_001378329.1; = p.G647Rfs*4 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 33/290 reads (11%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- NGDN | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- NHS | c.3092G>T p.R1031I | Missense Mutation (SNP) | VAF 68/781 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLGN1 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC2L | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NOL4L | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOX5 | c.80G>T p.W27L | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NR2C2 | c.185G>T p.G62V (on ENST00000393102; = p.G81V on NM_003298.5) | Missense Mutation (SNP) | VAF 42/775 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.67); called by muse, mutect2
- NRG1 | c.174C>A p.Y58* (on ENST00000523534; = p.Y205* on NM_013962.2) | Nonsense Mutation (SNP) | VAF 19/438 reads (4%) | called by muse, mutect2
- NSUN5 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- NUP133 | c.2425A>G p.I809V | Missense Mutation (SNP) | VAF 91/569 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NUP160 | c.3610G>T p.V1204F | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.027); called by muse, mutect2
- NUP205 | c.4784A>T p.D1595V | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- NUP93 | c.18dup p.G7Wfs*2 | Frame Shift Ins (INS) | VAF 24/171 reads (14%) | called by pindel, varscan2
- NYX | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- OGN | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR10K2 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 111/429 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- OR10Z1 | c.473del p.G158Efs*2 | Frame Shift Del (DEL) | VAF 91/582 reads (16%) | called by mutect2, pindel, varscan2
- OR11H6 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR11H6 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- OR2C3 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- OR2G3 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR3A3 | c.691del p.V231* | Frame Shift Del (DEL) | VAF 63/548 reads (11%) | called by mutect2, pindel, varscan2
- OR5B3 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR5H1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- OSBPL2 | c.618C>A p.F206L (on ENST00000313733 / NM_144498.4; = p.F194L on NM_014835.4) | Missense Mutation (SNP) | VAF 77/586 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OXTR | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- P2RY10 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, varscan2
- PAPLN | c.3017A>T p.E1006V (on ENST00000554301; = p.E979V on NM_173462.4) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- PAQR7 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PCBP3 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PCDH19 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PEDS1 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 129/537 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX5L | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 26/551 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- PHKB | c.2008T>G p.F670V | Missense Mutation (SNP) | VAF 69/694 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PIEZO2 | c.5180C>G p.P1727R | Missense Mutation (SNP) | VAF 61/576 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLA2G6 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 78/896 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2
- PLAG1 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLSCR4 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); called by muse, mutect2
- PLXNB3 | c.3688G>T p.G1230C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARG | c.1497G>T p.E499D (on ENST00000287820 / NM_015869.5; = p.E469D on NM_005037.7) | Missense Mutation (SNP) | VAF 48/626 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- PPP1R3F | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- PRDM9 | c.1625A>T p.H542L | Missense Mutation (SNP) | VAF 50/930 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PREX1 | c.3971A>T p.D1324V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKACG | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 139/572 reads (24%) | called by muse, mutect2, varscan2
- PRKX | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT6 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- PRPF3 | c.1167del p.W389Cfs*6 | Frame Shift Del (DEL) | VAF 110/625 reads (18%) | called by mutect2, pindel, varscan2
- PRSS37 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- PTPRB | c.4674A>T p.K1558N | Missense Mutation (SNP) | VAF 144/448 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PTPRD | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTPRQ | c.3638G>T p.W1213L (on ENST00000616559; = p.W1171L on NM_001145026.2) | Missense Mutation (SNP) | VAF 50/650 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PTPRZ1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- PURG | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- QRICH2 | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 26/704 reads (4%) | called by muse, mutect2
- RAB2B | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RANBP3L | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2
- RASA1 | c.2198dup p.E734Gfs*33 | Frame Shift Ins (INS) | VAF 40/228 reads (18%) | called by mutect2, pindel, varscan2
- RBM20 | c.1134dup p.G379Wfs*20 | Frame Shift Ins (INS) | VAF 25/241 reads (10%) | called by mutect2, pindel, varscan2
- RBM25 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- RC3H1 | c.2317C>G p.P773A | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- REC8 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RET | c.1452G>T p.M484I | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMKLA | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 39/645 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RIN2 | c.1853C>T p.S618F (on ENST00000255006 / NM_001242581.1; = p.S569F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/1544 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); called by muse, mutect2
- RRP7A | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.6524T>A p.M2175K | Missense Mutation (SNP) | VAF 93/744 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.8556G>T p.W2852C | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.11533C>G p.L3845V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SAMD9L | c.3671C>A p.S1224Y | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.181); called by muse, varscan2
- SAMD9L | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2
- SCAPER | c.2951C>T p.P984L | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SCML2 | c.1994T>C p.L665P | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN7A | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 108/496 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SCN7A | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC23IP | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- SERPINB4 | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 97/460 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SETBP1 | c.3533C>A p.A1178D | Missense Mutation (SNP) | VAF 92/526 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SETX | c.4567A>T p.I1523F | Missense Mutation (SNP) | VAF 152/670 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFSWAP | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SGIP1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SH2D4B | c.1288C>A p.L430M (on ENST00000646907; = p.S355Y on NM_207372.2) | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SH2D5 | c.1202G>T p.G401V (on ENST00000444387 / NM_001103161.2; = p.G317V on NM_001103160.2) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SH3BP5L | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 107/663 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOX | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 69/580 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SIMC1 | c.1124G>T p.S375I (on ENST00000443967 / NM_001308196.1; = p.S394I on NM_001308195.2) | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- SLC17A6 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 131/787 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SLC17A6 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 87/459 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC18A1 | c.260dup p.N87Kfs*7 | Frame Shift Ins (INS) | VAF 54/466 reads (12%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC4A7 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SLITRK3 | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SMAP2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOCS4 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SPATA31D1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 24/818 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SPATA31D3 | c.2595C>A p.H865Q | Missense Mutation (SNP) | VAF 105/744 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SRPX | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
- SSTR2 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 172/714 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SSU72P8 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2
- STARD9 | c.12802G>T p.A4268S | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2
- STEAP1B | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2
- STK32B | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2
- STMND1 | c.596C>G p.S199* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- SYT4 | c.632del p.L211Rfs*33 | Frame Shift Del (DEL) | VAF 52/370 reads (14%) | called by mutect2, pindel*, varscan2
- TAB3 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2
- TACR3 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TAF5L | c.1277dup p.A427Gfs*11 | Frame Shift Ins (INS) | VAF 138/957 reads (14%) | called by mutect2, pindel, varscan2
- TAZ | c.460+5G>T | Splice Region (SNP) | VAF 58/598 reads (10%) | called by muse, mutect2
- TBC1D8 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 99/623 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TBC1D8 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 97/618 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TBC1D8B | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TDRD15 | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); called by muse, mutect2
- TEX13C | c.2615G>C p.G872A | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); called by muse, mutect2
- TEX47 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- TIAM2 | c.3010C>A p.Q1004K | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- TIMD4 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 148/1022 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TM9SF3 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM14B | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 107/822 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TMEM59 | c.817-1G>A p.X273_splice | Splice Site (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- TMPRSS11B | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 72/478 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- TNKS2 | c.2751C>G p.I917M | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TRBV4-1 | c.61A>C p.T21P | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.109); called by muse, mutect2
- TRIM51GP | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 37/304 reads (12%) | called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 39/491 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM77 | c.1298T>A p.L433H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TRPC5 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TSEN2 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 58/726 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSPYL2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 84/648 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TTC28 | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 74/496 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- UBQLN3 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 28/554 reads (5%) | called by muse, mutect2
- UNC13C | c.3639T>A p.D1213E | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- UNC13C | c.3640G>T p.G1214W | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 50/888 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- USP26 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- USP9X | c.5611C>A p.H1871N | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- VAV3 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13D | c.3351G>T p.E1117D | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VSNL1 | c.316A>C p.N106H | Missense Mutation (SNP) | VAF 34/790 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- VWA3A | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WIZ | c.3029G>T p.G1010V (on ENST00000673675 / NM_001371589.1; = p.G187V on NM_001330395.4) | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- XKR3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- XRN2 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 108/773 reads (14%) | called by muse, mutect2, varscan2
- ZBTB24 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 91/527 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2470G>A p.A824T | Missense Mutation (SNP) | VAF 44/592 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZFP30 | c.1268C>G p.S423* | Nonsense Mutation (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- ZFP57 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF202 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- ZNF268 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 100/540 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF335 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZNF33A | c.517G>T p.G173W (on ENST00000458705 / NM_006974.3; = p.G174W on NM_006954.2) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF541 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 141/621 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF763 | c.935G>T p.C312F (on ENST00000358987 / NM_001367172.2; = p.C315F on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF804B | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF865 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF99 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZSCAN10 | c.905C>A p.P302Q (on ENST00000252463; = p.P357Q on NM_032805.3) | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.205); called by muse, mutect2
- ABCA13 | c.10758C>T p.S3586= | Silent (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- ACTRT2 | c.766C>T p.L256= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as rs1291330237, COSV101007596; called by muse, mutect2, varscan2
- ADAM12 | c.2235C>A p.T745= | Silent (SNP) | VAF 47/454 reads (10%) | called by muse, mutect2, varscan2
- ADGRA1 | c.105G>T p.G35= | Silent (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- ADGRB3 | c.1410C>T p.S470= | Silent (SNP) | VAF 72/368 reads (20%) | called by muse, mutect2, varscan2
- ADGRG4 | c.2220C>A p.S740= | Silent (SNP) | VAF 32/414 reads (8%) | called by muse, mutect2
- ANK3 | c.11241G>T p.A3747= | Silent (SNP) | VAF 43/398 reads (11%) | catalogued as COSV55059533; called by muse, mutect2, varscan2
- APOA5 | c.810C>A p.A270= | Silent (SNP) | VAF 119/465 reads (26%) | catalogued as COSV57062520; called by muse, mutect2, varscan2
- ARL11 | c.381T>A p.P127= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- ARMC5 | c.864C>T p.S288= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs1462281624; called by muse, mutect2, varscan2
- ASB18 | c.1054C>T p.L352= | Silent (SNP) | VAF 36/567 reads (6%) | called by muse, mutect2
- BRD1 | c.1125C>T p.T375= | Silent (SNP) | VAF 48/434 reads (11%) | called by muse, mutect2, varscan2
- C16orf96 | c.645C>T p.T215= | Silent (SNP) | VAF 17/497 reads (3%) | catalogued as rs975850437; called by muse, mutect2
- C8orf89 | c.327G>A p.E109= | Silent (SNP) | VAF 36/544 reads (7%) | catalogued as rs1291516696; called by muse, mutect2
- CAMK2A | c.48C>T p.F16= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as rs753516638, COSV62247051, COSV62247885; called by muse, mutect2, varscan2
- CCDC15 | c.1482G>T p.L494= | Silent (SNP) | VAF 142/565 reads (25%) | called by muse, mutect2, varscan2
- CCR10 | c.453G>C p.R151= | Silent (SNP) | VAF 57/246 reads (23%) | called by muse, mutect2, varscan2
- CD109 | c.2808G>A p.L936= | Silent (SNP) | VAF 29/214 reads (14%) | called by muse, mutect2, varscan2
- CDC42BPG | c.2127G>T p.L709= | Silent (SNP) | VAF 40/334 reads (12%) | catalogued as COSV100712130; called by muse, mutect2, varscan2
- CDH10 | c.2022C>G p.T674= | Silent (SNP) | VAF 249/983 reads (25%) | catalogued as COSV52586615; called by muse, mutect2, varscan2
- CES1 | c.453C>T p.T151= | Silent (SNP) | VAF 102/1534 reads (7%) | catalogued as rs1397356144, COSV100828665; called by muse, mutect2
- CNKSR2 | c.1884C>A p.A628= | Silent (SNP) | VAF 25/403 reads (6%) | called by muse, mutect2
- CNNM1 | c.1332A>G p.S444= | Silent (SNP) | VAF 35/329 reads (11%) | called by muse, mutect2, varscan2
- CNTN5 | c.2061C>A p.A687= | Silent (SNP) | VAF 74/335 reads (22%) | called by muse, mutect2, varscan2
- CPT1C | c.114C>G p.S38= | Silent (SNP) | VAF 117/430 reads (27%) | called by muse, mutect2, varscan2
- CRACDL | c.754C>T p.L252= | Silent (SNP) | VAF 186/1079 reads (17%) | called by muse, mutect2, varscan2
- CRISP3 | c.177T>C p.F59= (on ENST00000371159 / NM_001368123.1; = p.F41= on NM_006061.4) | Silent (SNP) | VAF 45/635 reads (7%) | called by muse, mutect2
- CSMD2 | c.960C>A p.P320= | Silent (SNP) | VAF 30/446 reads (7%) | called by muse, mutect2
- CTNND2 | c.199C>A p.R67= | Silent (SNP) | VAF 129/597 reads (22%) | catalogued as COSV58867697; called by muse, mutect2, varscan2
- CX3CR1 | c.183G>A p.K61= | Silent (SNP) | VAF 41/293 reads (14%) | catalogued as COSV64194972; called by muse, mutect2, varscan2
- CYP7B1 | c.1353C>G p.G451= | Silent (SNP) | VAF 26/649 reads (4%) | called by muse, mutect2
- DCC | c.1327C>A p.R443= | Silent (SNP) | VAF 26/600 reads (4%) | called by muse, mutect2
- DMRTB1 | c.357C>T p.F119= | Silent (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- DNAH11 | c.4353G>T p.A1451= | Silent (SNP) | VAF 37/299 reads (12%) | called by muse, mutect2, varscan2
- DOP1A | c.6489C>T p.L2163= | Silent (SNP) | VAF 20/291 reads (7%) | catalogued as rs970503246; called by muse, mutect2
- DPP6 | c.969C>A p.V323= (on ENST00000377770 / NM_001364500.2; = p.V261= on NM_001936.5) | Silent (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- DSP | c.2763C>T p.N921= | Silent (SNP) | VAF 28/464 reads (6%) | called by muse, mutect2
- EGR2 | c.777C>G p.P259= | Silent (SNP) | VAF 36/339 reads (11%) | catalogued as rs750955966; called by muse, mutect2, varscan2
- EMILIN2 | c.1539T>A p.G513= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- EMX2 | c.294C>T p.P98= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- EPB41L3 | c.1263G>T p.A421= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV100550068; called by muse, mutect2, varscan2
- EPHA6 | c.3012C>A p.L1004= | Silent (SNP) | VAF 35/311 reads (11%) | catalogued as rs1465391690; called by muse, mutect2, varscan2
- ERVFRD-1 | c.756C>A p.P252= | Silent (SNP) | VAF 71/243 reads (29%) | called by muse, mutect2, varscan2
- EVC2 | c.609G>T p.L203= | Silent (SNP) | VAF 73/372 reads (20%) | catalogued as COSV60390703; called by muse, mutect2, varscan2
- FAM43A | c.666G>C p.P222= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs748069915; called by muse, mutect2, varscan2
- FARP1 | c.1200T>C p.G400= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2
- FEZ1 | c.258C>G p.P86= | Silent (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- FLNC | c.7590C>A p.T2530= | Silent (SNP) | VAF 67/643 reads (10%) | called by muse, mutect2, varscan2
- GJD2 | c.345C>A p.A115= | Silent (SNP) | VAF 48/402 reads (12%) | called by muse, mutect2, varscan2
- GPC3 | c.921G>A p.V307= | Silent (SNP) | VAF 18/630 reads (3%) | catalogued as COSV100892972; called by muse, mutect2
- GRIN3B | c.1647C>T p.F549= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- GUCY2F | c.846T>C p.D282= | Silent (SNP) | VAF 42/365 reads (12%) | catalogued as COSV54306801; called by muse, mutect2
- HADHB | c.693C>T p.A231= | Silent (SNP) | VAF 38/327 reads (12%) | catalogued as rs768034989, CD031504; called by muse, mutect2, varscan2
- HCN4 | c.417C>A p.P139= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- HK3 | c.399G>T p.L133= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, varscan2
- HRNR | c.2742T>C p.G914= | Silent (SNP) | VAF 165/907 reads (18%) | called by muse, mutect2, varscan2
- IGHM | c.180G>C p.L60= | Silent (SNP) | VAF 28/829 reads (3%) | called by muse, mutect2
- IGKV2D-29 | c.214C>T p.L72= | Silent (SNP) | VAF 139/662 reads (21%) | called by muse, mutect2, varscan2
- IL21R | c.1125C>A p.S375= | Silent (SNP) | VAF 43/303 reads (14%) | called by muse, mutect2, varscan2
- ILF2 | c.229C>T p.L77= | Silent (SNP) | VAF 20/277 reads (7%) | called by muse, mutect2
- INO80E | c.321C>T p.P107= | Silent (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- IPO4 | c.1119C>G p.L373= | Silent (SNP) | VAF 18/654 reads (3%) | catalogued as COSV99937723; called by muse, mutect2
- IRF2 | c.228A>T p.T76= | Silent (SNP) | VAF 67/369 reads (18%) | called by muse, mutect2, varscan2
- ISM1 | c.477G>T p.R159= | Silent (SNP) | VAF 128/644 reads (20%) | called by muse, mutect2, varscan2
- ITIH2 | c.888C>A p.V296= | Silent (SNP) | VAF 69/550 reads (13%) | called by muse, mutect2, varscan2
- JRK | c.1440T>A p.G480= | Silent (SNP) | VAF 16/343 reads (5%) | called by muse, mutect2
- KCNA7 | c.681C>A p.R227= | Silent (SNP) | VAF 126/499 reads (25%) | catalogued as COSV55504582; called by muse, mutect2, varscan2
- KCNMA1 | c.1701C>A p.G567= | Silent (SNP) | VAF 67/506 reads (13%) | called by muse, mutect2, varscan2
- KIAA0930 | c.1149G>T p.T383= (on ENST00000336156 / NM_001009880.2; = p.T388= on NM_015264.2) | Silent (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4161C>T p.L1387= (on ENST00000321505; = p.L1684= on NM_012194.3) | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2
- KIAA1614 | c.1194C>A p.T398= | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2
- LHX4 | c.480C>A p.P160= | Silent (SNP) | VAF 206/953 reads (22%) | called by muse, mutect2, varscan2
- LRG1 | c.837C>G p.L279= | Silent (SNP) | VAF 21/595 reads (4%) | called by muse, mutect2
- LSG1 | c.375A>T p.P125= | Silent (SNP) | VAF 24/479 reads (5%) | called by muse, mutect2
- MAGEE1 | c.1110C>G p.P370= | Silent (SNP) | VAF 33/303 reads (11%) | called by muse, mutect2, varscan2
- MANEA | c.747G>A p.P249= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs376285454; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.109C>A p.R37= | Silent (SNP) | VAF 57/1004 reads (6%) | catalogued as rs760831587; called by muse, mutect2
- MECP2 | c.1308T>C p.T436= | Silent (SNP) | VAF 108/1029 reads (10%) | called by muse, mutect2, varscan2
- MEIS1 | c.942C>G p.L314= | Silent (SNP) | VAF 20/578 reads (3%) | catalogued as COSV99714214; called by muse, mutect2
- MKRN3 | c.765G>T p.G255= | Silent (SNP) | VAF 21/435 reads (5%) | called by muse, mutect2
- MN1 | c.2928A>T p.P976= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs1467690488; called by muse, mutect2, varscan2
- MRPL16 | c.9G>A p.R3= | Silent (SNP) | VAF 45/322 reads (14%) | called by muse, mutect2, varscan2
- MYH1 | c.1278A>T p.A426= | Silent (SNP) | VAF 85/437 reads (19%) | called by muse, mutect2, varscan2
- NAAA | c.660C>T p.I220= | Silent (SNP) | VAF 83/446 reads (19%) | called by muse, mutect2, varscan2
- NAV2 | c.1128A>G p.A376= (on ENST00000396087 / NM_001244963.2; = p.A353= on NM_145117.5) | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- NLGN4X | c.375C>A p.P125= | Silent (SNP) | VAF 68/726 reads (9%) | called by muse, mutect2
- NRN1 | c.243G>A p.T81= | Silent (SNP) | VAF 61/733 reads (8%) | catalogued as rs145961184; called by muse, mutect2
- NTS | c.450G>T p.R150= | Silent (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- OIT3 | c.693T>C p.N231= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- OR11H6 | c.882G>T p.L294= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as COSV100209934; called by muse, mutect2
- OR2L2 | c.522T>C p.N174= | Silent (SNP) | VAF 29/248 reads (12%) | called by muse, mutect2, varscan2
- OR5H1 | c.882T>C p.N294= | Silent (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- OR5H15 | c.342C>G p.L114= | Silent (SNP) | VAF 45/435 reads (10%) | catalogued as COSV100736734; called by muse, mutect2, varscan2
- OSBPL1A | c.474A>T p.T158= | Silent (SNP) | VAF 41/445 reads (9%) | called by muse, mutect2
- PCDH17 | c.2979T>C p.T993= | Silent (SNP) | VAF 30/458 reads (7%) | catalogued as rs1221439225; called by muse, mutect2
- PCDHA8 | c.1465C>T p.L489= | Silent (SNP) | VAF 171/863 reads (20%) | catalogued as COSV65330587; called by muse, mutect2, varscan2
- PCDHB1 | c.759G>A p.E253= | Silent (SNP) | VAF 54/357 reads (15%) | catalogued as rs137926825; called by muse, mutect2, varscan2
- PCDHB7 | c.1083C>A p.P361= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1554280086, COSV50753698, COSV50754712, COSV50767393; called by muse, mutect2
- PGBD1 | c.621G>T p.V207= | Silent (SNP) | VAF 68/512 reads (13%) | called by muse, mutect2, varscan2
- PIK3C2A | c.2391C>T p.D797= | Silent (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- PKD1L2 | c.2943C>A p.A981= | Silent (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- PLXNB3 | c.1402C>A p.R468= | Silent (SNP) | VAF 27/204 reads (13%) | catalogued as COSV62795465, COSV62803678; called by muse, mutect2, varscan2
- PNISR | c.699C>T p.P233= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs530877907, COSV100984397; called by muse, mutect2
- POU3F2 | c.1245C>A p.P415= | Silent (SNP) | VAF 56/324 reads (17%) | called by muse, mutect2, varscan2
- PPP1R32 | c.633C>A p.S211= | Silent (SNP) | VAF 40/254 reads (16%) | called by muse, mutect2, varscan2
- PTK7 | c.2799G>T p.A933= | Silent (SNP) | VAF 60/580 reads (10%) | catalogued as COSV57851448; called by muse, mutect2, varscan2
- PURG | c.438C>T p.S146= | Silent (SNP) | VAF 57/362 reads (16%) | catalogued as rs138893308; called by muse, mutect2, varscan2
- RHOBTB1 | c.1665C>T p.D555= | Silent (SNP) | VAF 51/462 reads (11%) | called by muse, mutect2, varscan2
- RNASE11 | c.393C>A p.V131= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- RNF128 | c.309G>C p.T103= | Silent (SNP) | VAF 36/260 reads (14%) | catalogued as COSV55252887, COSV99718274; called by muse, mutect2, varscan2
- RNF213 | c.6297C>A p.I2099= | Silent (SNP) | VAF 21/372 reads (6%) | called by muse, mutect2
- ROR2 | c.885C>A p.P295= | Silent (SNP) | VAF 68/262 reads (26%) | called by muse, mutect2, varscan2
- RTL1 | c.888G>A p.Q296= | Silent (SNP) | VAF 51/329 reads (16%) | called by muse, mutect2, varscan2
- RXFP3 | c.237G>T p.R79= | Silent (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- RXFP3 | c.840G>T p.L280= | Silent (SNP) | VAF 50/536 reads (9%) | catalogued as COSV100347183; called by muse, mutect2
- SBNO1 | c.2607C>T p.L869= (on ENST00000420886; = p.L868= on NM_018183.5) | Silent (SNP) | VAF 28/255 reads (11%) | catalogued as rs1218108946, COSV57343261; called by muse, mutect2, varscan2
- SEMA5B | c.991C>T p.L331= | Silent (SNP) | VAF 134/793 reads (17%) | called by muse, mutect2, varscan2
- SERPINA7 | c.798G>T p.L266= | Silent (SNP) | VAF 55/534 reads (10%) | catalogued as COSV59666663; called by mutect2, varscan2
- SETBP1 | c.3534C>A p.A1178= | Silent (SNP) | VAF 92/524 reads (18%) | catalogued as COSV56330334; called by muse, mutect2, varscan2
- SETD1A | c.2010G>T p.G670= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.105T>G p.A35= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as rs1045209348; called by muse, mutect2
- SLC17A8 | c.492C>T p.I164= | Silent (SNP) | VAF 56/550 reads (10%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1110C>A p.T370= | Silent (SNP) | VAF 94/402 reads (23%) | catalogued as rs756665459, COSV66154439; called by muse, mutect2, varscan2
- SLC6A17 | c.1692C>T p.P564= | Silent (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- SLC7A3 | c.180T>C p.D60= | Silent (SNP) | VAF 80/458 reads (17%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1284C>A p.P428= | Silent (SNP) | VAF 54/507 reads (11%) | called by muse, mutect2, varscan2
- SULT4A1 | c.114C>T p.I38= | Silent (SNP) | VAF 17/531 reads (3%) | catalogued as COSV50780822; called by muse, mutect2
- SYN2 | c.654C>A p.S218= | Silent (SNP) | VAF 41/290 reads (14%) | called by muse, mutect2, varscan2
- TBC1D22A | c.291G>T p.T97= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs147056286; called by muse, mutect2, varscan2
- TENM2 | c.3159C>A p.T1053= (on ENST00000518659 / NM_001122679.2; = p.T821= on NM_001080428.3) | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- TENT5D | c.294G>A p.Q98= | Silent (SNP) | VAF 102/533 reads (19%) | called by muse, varscan2
- TEX13A | c.717G>A p.E239= | Silent (SNP) | VAF 16/502 reads (3%) | catalogued as COSV61144104; called by muse, mutect2
- TIAM1 | c.3927A>G p.K1309= | Silent (SNP) | VAF 29/299 reads (10%) | called by muse, mutect2, varscan2
- TLR4 | c.1063A>C p.R355= (on ENST00000355622 / NM_138554.5; = p.R315= on NM_003266.4) | Silent (SNP) | VAF 58/278 reads (21%) | called by muse, mutect2, varscan2
- TMC2 | c.915T>A p.S305= | Silent (SNP) | VAF 66/339 reads (19%) | called by muse, mutect2, varscan2
- TMEM131L | c.4719G>C p.P1573= | Silent (SNP) | VAF 62/572 reads (11%) | catalogued as COSV53645432; called by muse, mutect2
- TMEM225 | c.498C>A p.T166= | Silent (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- TRPC5 | c.648C>A p.P216= | Silent (SNP) | VAF 36/215 reads (17%) | called by muse, mutect2, varscan2
- TTC24 | c.940C>A p.R314= | Silent (SNP) | VAF 31/358 reads (9%) | catalogued as COSV100964382; called by muse, mutect2
- TUBGCP3 | c.2274C>T p.I758= | Silent (SNP) | VAF 11/328 reads (3%) | called by muse, mutect2
- UGT3A1 | c.210G>A p.E70= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as rs1215906827; called by muse, mutect2
- UNC45A | c.1419C>T p.F473= | Silent (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- UNC80 | c.7644A>C p.A2548= | Silent (SNP) | VAF 79/386 reads (20%) | called by muse, mutect2, varscan2
- USH2A | c.7428C>T p.G2476= | Silent (SNP) | VAF 117/633 reads (18%) | catalogued as rs150372183; called by muse, mutect2, varscan2
- VMP1 | c.1188G>A p.Q396= | Silent (SNP) | VAF 27/649 reads (4%) | called by muse, mutect2
- VNN1 | c.693C>A p.T231= | Silent (SNP) | VAF 74/456 reads (16%) | catalogued as COSV63390805; called by muse, mutect2, varscan2
- VWA5B1 | c.99C>T p.A33= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as rs1389306565; called by muse, mutect2
- WAS | c.177T>G p.P59= | Silent (SNP) | VAF 84/609 reads (14%) | catalogued as CD941815; called by muse, mutect2, varscan2
- WNK2 | c.2298C>A p.A766= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV99945252; called by muse, mutect2, varscan2
- ZFHX4 | c.2271T>A p.S757= | Silent (SNP) | VAF 61/329 reads (19%) | catalogued as rs768311097; called by muse, mutect2, varscan2
- ZFPM1 | c.333G>A p.T111= | Silent (SNP) | VAF 47/519 reads (9%) | catalogued as rs778368181; called by muse, mutect2
- ZNF350 | c.315A>G p.E105= | Silent (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- ZP4 | c.1440T>C p.S480= | Silent (SNP) | VAF 37/289 reads (13%) | catalogued as rs764133810; called by muse, mutect2, varscan2
- ABCC8 | c.4411+31G>T | Intron (SNP) | VAF 16/383 reads (4%) | called by muse, mutect2
- AC068587.7 | chr8:12659552 C>A | 5'Flank (SNP) | VAF 60/430 reads (14%) | called by muse, varscan2
- AC092818.1 | n.276C>A | RNA (SNP) | VAF 30/373 reads (8%) | called by muse, mutect2
- AC092818.1 | n.275C>A | RNA (SNP) | VAF 28/357 reads (8%) | called by muse, mutect2
- AKT2 | c.-85+9887T>C | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- AL049777.1 | n.510+4558G>T | Intron (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ARCN1 | c.*544C>T | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ARPC5 | c.*4055G>T | 3'UTR (SNP) | VAF 101/615 reads (16%) | called by muse, mutect2, varscan2
- BSG | c.416-82A>T | Intron (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- CCDC191 | chr3:114056537 C>T | 5'Flank (SNP) | VAF 16/365 reads (4%) | called by muse, mutect2
- CCS | c.-22C>G | 5'UTR (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- CRISP2 | c.515+161A>T | Intron (SNP) | VAF 62/450 reads (14%) | called by muse, mutect2, varscan2
- CSNK1G1 | c.1108-7977A>G | Intron (SNP) | VAF 31/436 reads (7%) | called by muse, mutect2
- DCHS2 | n.2444C>A | RNA (SNP) | VAF 25/406 reads (6%) | called by muse, mutect2
- DHX40P1 | n.1104C>A | RNA (SNP) | VAF 54/770 reads (7%) | called by muse, mutect2
- DHX40P1 | n.1103C>A | RNA (SNP) | VAF 54/766 reads (7%) | called by muse, mutect2
- DMTF1 | c.711-176A>G | Intron (SNP) | VAF 40/404 reads (10%) | catalogued as COSV100487537; called by muse, mutect2
- ERVV-1 | chr19:53009990 G>T | 5'Flank (SNP) | VAF 68/258 reads (26%) | called by muse, mutect2, varscan2
- FAM110C | c.*25G>T | 3'UTR (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- FANCA | c.1225+47G>T | Intron (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2
- FOXP2 | c.*2545G>T | 3'UTR (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102053C>T | Intron (SNP) | VAF 24/147 reads (16%) | catalogued as rs747308599; called by muse, mutect2, varscan2
- HDDC3 | c.409+120G>C | Intron (SNP) | VAF 20/506 reads (4%) | catalogued as rs1443701434; called by muse, mutect2
- IGFN1 | c.1242-450G>T | Intron (SNP) | VAF 45/249 reads (18%) | catalogued as COSV55168251; called by muse, mutect2, varscan2
- KCNQ2 | c.*48del | 3'UTR (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- LIAS | chr4:39458927 T>G | 5'Flank (SNP) | VAF 22/742 reads (3%) | called by muse, mutect2
- MITF | c.102-12834C>T | Intron (SNP) | VAF 26/357 reads (7%) | catalogued as rs778608602; called by muse, mutect2
- MRNIP | c.126+1957G>T | Intron (SNP) | VAF 68/399 reads (17%) | called by muse, mutect2, varscan2
- MSL3 | c.102+336G>C | Intron (SNP) | VAF 38/331 reads (11%) | catalogued as rs777434724; called by muse, mutect2
- MTCL1 | chr18:8831823 C>A | 3'Flank (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- MTG1 | c.573+59C>A | Intron (SNP) | VAF 50/528 reads (9%) | called by muse, mutect2, varscan2
- MUC19 | n.5999C>A | RNA (SNP) | VAF 101/652 reads (15%) | catalogued as rs886322957; called by muse, mutect2, varscan2
- MYCL | c.-363G>T | 5'UTR (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- NSG2 | c.*229_*230insTG | 3'UTR (INS) | VAF 98/580 reads (17%) | called by muse*, mutect2, varscan2*
- NSG2 | c.*231_*232del | 3'UTR (DEL) | VAF 95/583 reads (16%) | called by muse*, mutect2, varscan2*
- OBP2B | c.277+243C>T | Intron (SNP) | VAF 88/503 reads (17%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53396A>G | Intron (SNP) | VAF 67/483 reads (14%) | catalogued as rs1176739032; called by muse, mutect2, varscan2
- PPP1R13B | c.*511G>C | 3'UTR (SNP) | VAF 22/730 reads (3%) | called by muse, mutect2
- PYGL | c.1519-28G>T | Intron (SNP) | VAF 66/486 reads (14%) | catalogued as COSV53585206; called by muse, mutect2, varscan2
- RBMX | chrX:136872328 A>C | 3'Flank (SNP) | VAF 51/492 reads (10%) | called by muse, mutect2, varscan2
- RGS2 | c.-5C>A | 5'UTR (SNP) | VAF 103/608 reads (17%) | catalogued as rs751951851; called by muse, mutect2, varscan2
- RNA5S17 | chr1:228650250 G>C | 5'Flank (SNP) | VAF 78/515 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-3 | n.63C>A | RNA (SNP) | VAF 36/810 reads (4%) | called by muse, mutect2
- SPTA1 | c.2465-30C>A | Intron (SNP) | VAF 104/517 reads (20%) | catalogued as rs1316769825; called by muse, mutect2, varscan2
- SUGCT | c.1089+2732G>T | Intron (SNP) | VAF 43/475 reads (9%) | called by muse, mutect2
- TAFA5 | c.112+56826G>T | Intron (SNP) | VAF 61/393 reads (16%) | catalogued as COSV60996550; called by muse, mutect2, varscan2
- TCF4 | c.287-8999G>T | Intron (SNP) | VAF 27/222 reads (12%) | catalogued as rs916780156; called by muse, mutect2, varscan2
- TEKT4P2 | n.414C>A | RNA (SNP) | VAF 37/387 reads (10%) | called by muse, mutect2, varscan2
- TIE1 | c.1043-40C>A | Intron (SNP) | VAF 87/524 reads (17%) | called by muse, mutect2, varscan2
- TNNT3 | c.116-50G>A | Intron (SNP) | VAF 54/417 reads (13%) | catalogued as rs777783710, COSV53488726; called by muse, mutect2, varscan2
- TPM1 | c.772+90G>T | Intron (SNP) | VAF 62/397 reads (16%) | called by muse, mutect2, varscan2
- TRIM9 | c.1604-3889A>T | Intron (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2
- TRIP4 | c.1679-4243C>A | Intron (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37795298 A>G | 5'Flank (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2
- UBL4A | c.155-34G>A | Intron (SNP) | VAF 40/215 reads (19%) | catalogued as rs1557212803; called by muse, mutect2, varscan2
- VIM | c.1008+13C>T | Intron (SNP) | VAF 62/678 reads (9%) | called by muse, mutect2
- WDR33 | c.626+350C>G | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- XIRP2 | c.-55G>A | 5'UTR (SNP) | VAF 51/264 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.*10C>A | 3'UTR (SNP) | VAF 18/484 reads (4%) | catalogued as rs983350737, COSV67170927; called by muse, mutect2
- ZNF208 | c.*456_*457del | 3'UTR (DEL) | VAF 33/252 reads (13%) | called by mutect2, pindel*, varscan2*
